Somatic mutation profile of tumor specimen 722378ea-d1a7-4cfc-aca5-ba45f9 (aliquot 722378ea-d1a7-4cfc-aca5-ba45f9_D6) from CPTAC case 11CO019, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 722378ea-d1a7-4cfc-aca5-ba45f9: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74882fbc-5de8-4114-9bed-7a49650c07bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7303fb7b-e7a6-4753-be4d-1e3d29 (Blood Derived Normal), aliquot 7303fb7b-e7a6-4753-be4d-1e3d29_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f46026f0-c043-4363-b26f-84a1a9e97aec

The open-access MAF lists 180 somatic variants for this specimen: 122 protein-altering or splice-affecting, 41 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 41, Nonsense Mutation 12, Intron 9, 5'Flank 3, Frame Shift Del 3, Frame Shift Ins 3, Splice Region 3, RNA 2, 3'Flank 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 74/262 reads (28%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1517G>T p.G506V (on ENST00000288602 / NM_001374244.1; = p.G466V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.167A>C p.Q56P | Missense Mutation (SNP) | VAF 78/289 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs1057519729, COSV61068787; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6016G>C p.V2006L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV63868121, COSV63871144, COSV63874589; called by muse, mutect2, varscan2
- PPOX | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 68/428 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918325, CM961146; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 162/308 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1131691025, COSV52677105, COSV52952688; ClinVar: uncertain significance; called by mutect2, varscan2
- AC006059.2 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs769257896, COSV59606510; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 68/372 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs587687025, COSV54999960; called by mutect2, varscan2
- AKAP12 | c.4781C>T p.T1594M | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs776715837, COSV53575554; called by muse, mutect2, varscan2
- AKAP9 | c.4787G>A p.R1596Q | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755498039, COSV62343357; called by muse, mutect2, varscan2
- APC | c.4464_4465dup p.L1489Yfs*19 | Frame Shift Ins (INS) | VAF 42/141 reads (30%) | catalogued as CI002198, COSV57330589; called by mutect2, pindel, varscan2
- ASPH | c.398A>G p.Q133R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.253); catalogued as rs374279734; called by muse, mutect2, varscan2
- AXIN2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61057792; called by muse, mutect2
- BCAS3 | c.1721C>T p.S574L (on ENST00000390652 / NM_001353144.2; = p.S559L on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs959545152, COSV66783081; called by muse, mutect2, varscan2
- BCL6 | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV51649830; called by muse, mutect2, varscan2
- CD1D | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 99/302 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as COSV63810023; called by muse, mutect2, varscan2
- CD93 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as rs762071141, COSV55669405, COSV99848760; called by muse, mutect2, varscan2
- CDH10 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52569583; called by muse, mutect2
- CIDEA | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.88); catalogued as rs372580595; called by muse, mutect2, varscan2
- CLCN1 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 178/378 reads (47%) | SIFT tolerated (0.99); PolyPhen benign (0.021); catalogued as rs139158852; called by muse, mutect2, varscan2
- COL15A1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 67/398 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as rs199564502, COSV100897694; called by muse, mutect2, varscan2
- COL5A1 | c.4481C>T p.P1494L | Missense Mutation (SNP) | VAF 71/324 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs773728118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAOA | c.443C>G p.T148S | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV61601551; called by muse, mutect2, varscan2
- DCBLD2 | c.61G>C p.A21P | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as COSV104400459; called by muse, mutect2
- DNHD1 | c.9669+4G>A | Splice Region (SNP) | VAF 15/328 reads (5%) | catalogued as rs1220522650; called by muse, mutect2
- EFCAB8 | c.3440C>T p.P1147L | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs575918372; called by muse, mutect2, varscan2
- GAN | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 94/315 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs537289482, CM159742, COSV73720764; called by muse, mutect2, varscan2
- GRIK5 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs143057585, COSV99490242; called by muse, mutect2, varscan2
- GRM7 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1032302204, COSV63142847, COSV63157383; called by muse, mutect2
- H2AC17 | c.113del p.G38Afs*22 | Frame Shift Del (DEL) | VAF 90/212 reads (42%) | catalogued as COSV58152259; called by mutect2, pindel, varscan2
- HECW2 | c.3443C>T p.S1148L | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99647500; called by muse, mutect2, varscan2
- HMCN1 | c.15262C>T p.R5088C | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as rs536109375, COSV54937382; called by muse, mutect2, varscan2
- HNRNPK | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV61088231, COSV61089679; called by muse, mutect2, varscan2
- HTR1A | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 22/834 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1177483577; called by muse, mutect2
- IGFBP4 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | catalogued as COSV54096586; called by muse, mutect2, varscan2
- KIF14 | c.2434C>G p.L812V | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs1397006693; called by muse, mutect2, varscan2
- KLHL38 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 98/347 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs780188773, COSV100384445, COSV58086288; called by muse, mutect2, varscan2
- LCT | c.5134C>T p.R1712C | Missense Mutation (SNP) | VAF 16/273 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs1353835855; called by muse, mutect2
- LIM2 | c.386G>A p.R129H (on ENST00000596399 / NM_001161748.2; = p.R171H on NM_030657.4) | Missense Mutation (SNP) | VAF 139/334 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs371415135, COSV99702282; called by muse, mutect2, varscan2
- LRP2 | c.11207G>A p.R3736H | Missense Mutation (SNP) | VAF 129/487 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752156045, COSV55573428; called by muse, mutect2, varscan2
- MAP2K6 | c.892A>T p.N298Y | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV63006965; called by muse, mutect2, varscan2
- MGA | c.8147C>T p.T2716M (on ENST00000219905 / NM_001164273.1; = p.T2507M on NM_001080541.2) | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs763664608, COSV54958457; called by muse, mutect2, varscan2
- MGAT4C | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs768547952, COSV100153072; called by muse, mutect2, varscan2
- MSH4 | c.2766_2768del p.E922del | In Frame Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs751582756; called by pindel, varscan2
- MYCBP2 | c.7011G>T p.M2337I (on ENST00000357337; = p.M2375I on NM_015057.5) | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.48); catalogued as rs1484863383; called by muse, mutect2
- NFRKB | c.1577G>A p.R526H (on ENST00000446488 / NM_001143835.2; = p.R551H on NM_006165.3) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs752427089; called by muse, mutect2, varscan2
- OR4C16 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 107/234 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58942185, COSV58942718; called by muse, mutect2, varscan2
- PAK3 | c.565G>T p.E189* (on ENST00000262836 / NM_001324328.2; = p.E174* on NM_002578.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 73/188 reads (39%) | catalogued as COSV99457340; called by muse, mutect2, varscan2
- PARD3B | c.3304C>T p.R1102W (on ENST00000406610 / NM_001302769.2; = p.R1033W on NM_057177.7) | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as rs369194609; called by muse, mutect2, varscan2
- PARVB | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs750285011, COSV58684424; called by muse, mutect2, varscan2
- PCDH19 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 17/465 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV55261394; called by muse, mutect2
- PGK2 | c.1034G>T p.W345L | Missense Mutation (SNP) | VAF 170/375 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV100505671; called by muse, mutect2, varscan2
- PGP | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs760284351; called by muse, mutect2, varscan2
- PITPNM3 | c.2381C>T p.S794L | Missense Mutation (SNP) | VAF 330/641 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1354990286; called by muse, mutect2, varscan2
- PTPN14 | c.1664C>T p.T555M | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs776055399, COSV65281112, COSV65289088; called by muse, mutect2, varscan2
- RABL6 | c.329G>C p.R110P | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV61039738; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RNPC3 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63715370; called by muse, mutect2, varscan2
- RPP25L | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 60/374 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs149551348; called by muse, mutect2, varscan2
- RTL1 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.762); catalogued as rs1428856167, COSV101128355; called by muse, mutect2, varscan2
- RTP2 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); catalogued as rs778642249, COSV100833014; called by muse, mutect2, varscan2
- RYR2 | c.1357A>C p.S453R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.877); catalogued as COSV63675761; called by muse, mutect2, varscan2
- SCN4A | c.4888G>A p.D1630N | Missense Mutation (SNP) | VAF 272/575 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs540950122, COSV71126063; called by muse, mutect2, varscan2
- SLC12A7 | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 86/311 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as rs770149865; called by muse, mutect2, varscan2
- TBL1X | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.887); catalogued as rs771404927; called by muse, mutect2, varscan2
- TEKT2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 166/526 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs142695740, COSV52880721; called by muse, mutect2, varscan2
- TERT | c.2516C>T p.T839M | Missense Mutation (SNP) | VAF 77/288 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748503447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TFE3 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 10/127 reads (8%) | catalogued as COSV59947222; called by muse, mutect2
- TMEM179 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as rs368802867; called by muse, mutect2, varscan2
- TMEM42 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs757773130; called by muse, mutect2
- TNFAIP2 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60695733; called by muse, mutect2, varscan2
- TPPP | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs371401446; called by muse, mutect2, varscan2
- TRIM49C | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as rs930661960; called by muse, mutect2, varscan2
- TTN | c.48038C>T p.P16013L (on ENST00000591111; = p.P8589L on NM_003319.4) | Missense Mutation (SNP) | VAF 43/171 reads (25%) | PolyPhen benign (0.356); catalogued as rs762800771, COSV60035575; called by muse, mutect2, varscan2
- WSCD2 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 87/307 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV54577557; called by muse, mutect2, varscan2
- ZFHX4 | c.8693G>A p.R2898H | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.315); catalogued as rs755881840, COSV50495239; called by muse, varscan2
- ZNF680 | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.408); catalogued as COSV100549252; called by muse, mutect2, varscan2
- ADAMTS12 | c.3688G>T p.E1230* | Nonsense Mutation (SNP) | VAF 80/286 reads (28%) | called by muse, mutect2, varscan2
- ADRA2C | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 72/359 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADRM1 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 209/436 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BPTF | c.4743G>T p.L1581F | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BSN | c.1787C>A p.S596Y | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- CCR8 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 79/245 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFHR4 | c.736C>A p.Q246K (on ENST00000367416 / NM_001201551.2; = p.Q247K on NM_001201550.3) | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.039); called by muse, mutect2
- CFTR | c.4172dup p.F1392Ifs*3 | Frame Shift Ins (INS) | VAF 103/234 reads (44%) | called by mutect2, varscan2
- CHRNA4 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 96/441 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- CRYBG2 | c.3507+2_3507+32delinsCTTAAGAGA p.X1169_splice | Splice Site (DEL) | VAF 11/78 reads (14%) | called by pindel, varscan2*
- CTNNB1 | c.1370G>A p.R457K | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CYP11B1 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 162/568 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- CYP2S1 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- DEFB121 | c.60C>G p.V20= | Splice Region (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- DNAH2 | c.6871T>G p.Y2291D | Missense Mutation (SNP) | VAF 86/165 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- FBXW7 | c.1129A>T p.K377* (on ENST00000281708 / NM_001349798.2; = p.K297* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- FOXL1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 62/518 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- FRMD4A | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- GNAO1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- GSX1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- HAS1 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.069); called by muse, varscan2
- KLHL28 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- NKD1 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 40/167 reads (24%) | called by muse, mutect2, varscan2
- ODF1 | c.636C>A p.C212* | Nonsense Mutation (SNP) | VAF 19/209 reads (9%) | called by muse, mutect2
- OR2T27 | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 79/365 reads (22%) | called by muse, mutect2, varscan2
- OR52N5 | c.534C>A p.C178* | Nonsense Mutation (SNP) | VAF 25/370 reads (7%) | called by muse, mutect2
- PLS3 | c.500G>A p.C167Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLR3F | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POTEI | c.2413C>A p.L805M | Missense Mutation (SNP) | VAF 272/950 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PRSS23 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 90/193 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- PTPRT | c.2411C>A p.A804D | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SDK1 | c.1211_1212del p.V404Gfs*59 | Frame Shift Del (DEL) | VAF 64/166 reads (39%) | called by pindel, varscan2
- SEMA3C | c.1754dup p.N585Kfs*2 | Frame Shift Ins (INS) | VAF 14/71 reads (20%) | called by mutect2, pindel, varscan2
- SLC38A4 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC66A3 | c.28A>G p.N10D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SYNE1 | c.16208T>C p.V5403A (on ENST00000367255 / NM_182961.4; = p.V5332A on NM_033071.3) | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- TCP11X2 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); called by mutect2, varscan2
- TEP1 | c.6842C>A p.A2281E | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM272 | c.201G>A p.K67= | Splice Region (SNP) | VAF 41/125 reads (33%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.2620G>C p.D874H | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- USP13 | c.1434A>C p.E478D | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UTP6 | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 13/267 reads (5%) | called by muse, mutect2
- VPS54 | c.2791C>T p.H931Y | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2
- VWCE | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF750 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 176/306 reads (58%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ABCA2 | c.5553G>A p.K1851= (on ENST00000614293; = p.K1821= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/275 reads (35%) | catalogued as rs758719613; called by mutect2, varscan2
- ANK3 | c.10158G>A p.G3386= | Silent (SNP) | VAF 52/238 reads (22%) | catalogued as COSV55086869; called by muse, mutect2, varscan2
- CCDC185 | c.1236C>T p.A412= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as rs1269220603; called by muse, varscan2
- CLHC1 | c.1146G>A p.R382= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs751253161; called by muse, mutect2, varscan2
- COL9A2 | c.1314C>T p.R438= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as rs1314555899; called by muse, mutect2, varscan2
- DNAJC5B | c.240C>T p.Y80= | Silent (SNP) | VAF 49/197 reads (25%) | catalogued as COSV52536553; called by muse, mutect2, varscan2
- FAM171A2 | c.816G>A p.K272= | Silent (SNP) | VAF 68/133 reads (51%) | called by muse, mutect2, varscan2
- FLG | c.8820T>C p.H2940= | Silent (SNP) | VAF 65/1048 reads (6%) | catalogued as rs772020198; called by muse, mutect2
- FLNC | c.4029C>T p.G1343= | Silent (SNP) | VAF 82/906 reads (9%) | catalogued as rs767426611, COSV57949422; called by muse, mutect2
- GALNT14 | c.1554C>T p.L518= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs774598779, COSV61111684; called by muse, mutect2, varscan2
- GET4 | c.585C>T p.F195= | Silent (SNP) | VAF 44/188 reads (23%) | catalogued as rs754149897; called by muse, mutect2, varscan2
- GPR35 | c.924C>T p.L308= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as rs142915042; called by muse, mutect2, varscan2
- IRX4 | c.201C>T p.A67= | Silent (SNP) | VAF 39/161 reads (24%) | catalogued as rs374621441; called by muse, mutect2, varscan2
- LRFN1 | c.747C>T p.F249= | Silent (SNP) | VAF 49/418 reads (12%) | catalogued as rs755225764, COSV99952645; called by muse, mutect2, varscan2
- MARCHF1 | c.624C>T p.F208= (on ENST00000274056; = p.F191= on NM_017923.4) | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV56830701; called by muse, mutect2, varscan2
- NPHP3 | c.249G>A p.E83= | Silent (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- OR2L3 | c.861C>A p.I287= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, varscan2
- PALD1 | c.1758C>T p.S586= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as rs778748768, COSV99698697; called by muse, mutect2, varscan2
- PCDHB10 | c.2136G>A p.A712= | Silent (SNP) | VAF 55/288 reads (19%) | catalogued as rs1554284470, COSV53382371; called by muse, mutect2, varscan2
- PCDHB8 | c.1344C>T p.N448= | Silent (SNP) | VAF 133/687 reads (19%) | catalogued as rs1554281186, COSV50753525; called by muse, mutect2, varscan2
- PEX11B | c.231A>G p.L77= | Silent (SNP) | VAF 23/184 reads (13%) | catalogued as rs199646545; called by muse, mutect2, varscan2
- POLD2 | c.447C>T p.D149= | Silent (SNP) | VAF 125/266 reads (47%) | catalogued as rs775577294; called by muse, mutect2, varscan2
- POMT1 | c.396C>T p.A132= | Silent (SNP) | VAF 109/307 reads (36%) | catalogued as rs375288218; called by muse, mutect2, varscan2
- PROB1 | c.315G>A p.T105= | Silent (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- PTPRM | c.3564G>A p.E1188= | Silent (SNP) | VAF 38/168 reads (23%) | called by muse, mutect2, varscan2
- PTPRS | c.2853G>T p.L951= | Silent (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- RESF1 | c.2538T>A p.G846= | Silent (SNP) | VAF 37/135 reads (27%) | called by muse, mutect2, varscan2
- S100A7A | c.102G>A p.T34= | Silent (SNP) | VAF 61/179 reads (34%) | catalogued as rs370692845; called by muse, mutect2, varscan2
- SALL2 | c.2625G>A p.P875= | Silent (SNP) | VAF 104/318 reads (33%) | catalogued as rs750778517; called by muse, varscan2
- SIX3 | c.978C>T p.S326= | Silent (SNP) | VAF 76/260 reads (29%) | catalogued as rs1341424178; called by muse, mutect2, varscan2
- SLC12A5 | c.948G>A p.T316= (on ENST00000454036 / NM_001134771.2; = p.T293= on NM_020708.5) | Silent (SNP) | VAF 116/457 reads (25%) | catalogued as rs138406290, COSV99717135; called by muse, mutect2, varscan2
- SLITRK5 | c.102C>A p.V34= | Silent (SNP) | VAF 77/321 reads (24%) | catalogued as COSV100281081, COSV61525892; called by muse, mutect2, varscan2
- SNRPA1 | c.642G>T p.L214= | Silent (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- SYNPO | c.2115C>A p.I705= (on ENST00000394243 / NM_001166208.2; = p.I461= on NM_007286.6) | Silent (SNP) | VAF 78/243 reads (32%) | called by muse, mutect2, varscan2
- TAB1 | c.1131G>A p.P377= | Silent (SNP) | VAF 72/184 reads (39%) | catalogued as rs369807240; called by muse, mutect2, varscan2
- TMEM241 | c.270G>A p.L90= | Silent (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- TMEM44 | c.441G>A p.P147= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as rs760320772, COSV56450986; called by muse, mutect2, varscan2
- TMEM67 | c.606G>A p.G202= | Silent (SNP) | VAF 40/156 reads (26%) | called by muse, mutect2, varscan2
- TRPS1 | c.1830G>A p.S610= (on ENST00000220888 / NM_001330599.2; = p.S623= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 125/481 reads (26%) | catalogued as rs751550383, COSV55237292, COSV55246645; called by muse, mutect2, varscan2
- VPS4A | c.360G>A p.E120= | Silent (SNP) | VAF 32/114 reads (28%) | called by muse, mutect2, varscan2
- ZNF827 | c.1554G>A p.S518= | Silent (SNP) | VAF 30/282 reads (11%) | catalogued as rs769451898; called by muse, mutect2
- ARMCX4 | c.1039-2773A>G | Intron (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- CICP28 | chr7:56812077 C>T | 3'Flank (SNP) | VAF 50/253 reads (20%) | catalogued as rs533190685; called by muse, mutect2, varscan2
- FHL1 | chrX:136146982 G>A | 5'Flank (SNP) | VAF 11/83 reads (13%) | catalogued as rs1349308573; called by muse, mutect2, varscan2
- FSHR | c.374+2570G>A | Intron (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- LINC00293 | n.535G>T | RNA (SNP) | VAF 77/283 reads (27%) | called by muse, mutect2, varscan2
- LINC00602 | n.1137G>A | RNA (SNP) | VAF 55/140 reads (39%) | called by muse, mutect2, varscan2
- PAX6 | c.11-44C>G | Intron (SNP) | VAF 20/204 reads (10%) | catalogued as rs1294887059; called by muse, mutect2
- PXDN | c.-7G>T | 5'UTR (SNP) | VAF 4/6 reads (67%) | called by mutect2, varscan2
- RAP1GAP | c.1429-901C>T | Intron (SNP) | VAF 14/154 reads (9%) | catalogued as rs769852665; called by muse, mutect2
- REEP2 | c.32+565C>A | Intron (SNP) | VAF 29/116 reads (25%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791158 C>T | 5'Flank (SNP) | VAF 33/232 reads (14%) | catalogued as rs369065315; called by muse, mutect2, varscan2
- RPL9 | c.162+92G>A | Intron (SNP) | VAF 52/332 reads (16%) | catalogued as rs766257933; called by muse, mutect2, varscan2
- SARS2 | c.394-39del | Intron (DEL) | VAF 46/148 reads (31%) | called by mutect2, pindel, varscan2
- SNORD114-23 | chr14:100987119 G>A | 3'Flank (SNP) | VAF 13/61 reads (21%) | catalogued as rs747547100; called by muse, mutect2, varscan2
- TMEM128 | c.97+17G>A | Intron (SNP) | VAF 8/55 reads (15%) | catalogued as rs1391535708; called by muse, mutect2, varscan2
- TNK2 | chr3:195911820 G>A | 5'Flank (SNP) | VAF 40/143 reads (28%) | catalogued as rs1486018455; called by muse, mutect2, varscan2
- UBAP2 | c.1969+68C>T | Intron (SNP) | VAF 23/92 reads (25%) | catalogued as rs768966490; called by muse, mutect2, varscan2
